Somatic mutation profile of tumor specimen TCGA-A2-A0CT-01A (aliquot TCGA-A2-A0CT-01A-31W-A071-09) from TCGA case TCGA-A2-A0CT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.1 years (25,959 days).
Specimen TCGA-A2-A0CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a228a3b8-e591-452e-8996-bfa72236c26e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0CT-10A (Blood Derived Normal), aliquot TCGA-A2-A0CT-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbc95bfe-12ce-4fc5-88d4-0c93913d50c0

The open-access MAF lists 102 somatic variants for this specimen: 77 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 70, Silent 25, Nonsense Mutation 3, In Frame Ins 1, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.2445G>C p.Q815H (on ENST00000326195 / NM_001025091.2; = p.Q777H on NM_001090.3) | Missense Mutation (SNP) | VAF 91/662 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.737); catalogued as rs1221150048, COSV100400860, COSV58230056; called by muse, mutect2, varscan2
- ADCY7 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV54269196; called by muse, mutect2
- ADGRG3 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs764461732, COSV59651947, COSV59652653; called by muse, mutect2, varscan2
- AKAP12 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99483439; called by muse, mutect2, varscan2
- ANK2 | c.2728C>G p.L910V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV52176946; called by muse, mutect2, varscan2
- ANKRD12 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100041397; called by muse, mutect2, varscan2
- AP4E1 | c.3011C>T p.T1004I | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV99956700; called by muse, mutect2
- BTNL3 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61565356, COSV61565438; called by muse, mutect2, varscan2
- CCDC40 | c.1969C>A p.Q657K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV66476897; called by muse, mutect2, varscan2
- CDH2 | c.1949G>C p.R650T | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV52271391, COSV52289630; called by muse, mutect2, varscan2
- CDK2 | c.688G>T p.V230F | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99906736; called by muse, mutect2
- CDYL | c.1447G>A p.D483N (on ENST00000328908 / NM_001368125.1; = p.D429N on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/77 reads (79%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV59360912; called by muse, mutect2, varscan2
- CEP19 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 70/142 reads (49%) | catalogued as COSV56360558; called by muse, mutect2, varscan2
- CLASP2 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV56289247; called by muse, mutect2, varscan2
- CNGA3 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs200819699, CM071619, COSV55622355; called by muse, mutect2, varscan2
- CTNND2 | c.2068C>T p.H690Y | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as rs140646504; called by muse, mutect2
- EFCAB5 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 258/878 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs553413830, COSV57933864; called by muse, mutect2, varscan2
- EXT1 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); catalogued as COSV65482699; called by muse, mutect2, varscan2
- FBXO22 | c.154T>C p.W52R | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51194796; called by muse, mutect2, varscan2
- GPATCH2L | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as COSV99833665; called by muse, mutect2
- GRK4 | c.1443C>G p.I481M (on ENST00000398052 / NM_182982.3; = p.I449M on NM_005307.3) | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61670366; called by muse, mutect2, varscan2
- H2AC15 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs188027160; called by muse, mutect2, varscan2
- HCN4 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1429346819, COSV56085749; called by muse, mutect2, varscan2
- HLA-DPA1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101343120; called by muse, mutect2
- IFI16 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 30/598 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99857636; called by muse, mutect2
- INPP5F | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | catalogued as COSV62822742; called by muse, mutect2, varscan2
- ITK | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs1293136647, COSV70064202; called by muse, mutect2, varscan2
- KIF11 | c.1798G>T p.V600F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV53272492; called by muse, mutect2, varscan2
- KLF8 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1298321992, COSV100808256; called by muse, mutect2
- KMT2D | c.10760A>T p.E3587V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56467661; called by muse, mutect2, varscan2
- KRIT1 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.867); catalogued as COSV100388782, COSV60667575; called by muse, mutect2
- KRT1 | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); catalogued as COSV52868217; called by muse, mutect2, varscan2
- LARS1 | c.944G>A p.G315E (on ENST00000394434 / NM_020117.11; = p.G288E on NM_016460.3) | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV50982794; called by muse, mutect2, varscan2
- LRRIQ3 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV100598983, COSV63047582; called by muse, mutect2, varscan2
- LTBP2 | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs778443565, COSV56211477; called by muse, mutect2, varscan2
- LYN | c.627A>T p.K209N | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV70206145; called by muse, mutect2, varscan2
- LYST | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1444650346, COSV67710984; called by muse, mutect2, varscan2
- MCRS1 | c.889C>G p.R297G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV57790829, COSV57791967; called by muse, mutect2, varscan2
- MYH10 | c.5165C>T p.S1722F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1020957538, COSV52606744; called by muse, mutect2, varscan2
- MYH10 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs778892637, COSV52606770; called by muse, mutect2, varscan2
- MYH11 | c.4098C>G p.I1366M | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs778694636, COSV55562852; called by muse, mutect2, varscan2
- NAV2 | c.4325G>T p.S1442I (on ENST00000396087 / NM_001244963.2; = p.S1419I on NM_145117.5) | Missense Mutation (SNP) | VAF 28/423 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV100216989; called by muse, mutect2
- NUDT5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58502467; called by muse, mutect2, varscan2
- OR10A6 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 138/488 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs267603212, COSV59164532; called by muse, mutect2, varscan2
- OR5T3 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV100282819, COSV57379753; called by muse, mutect2
- PA2G4 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.528); catalogued as COSV100306508, COSV57568316; called by muse, mutect2
- PCDHA4 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV100793423; called by muse, varscan2
- PHF20L1 | c.725T>A p.L242H | Missense Mutation (SNP) | VAF 42/449 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99621354; called by muse, mutect2
- POLR2B | c.90C>T p.I30= | Splice Region (SNP) | VAF 8/117 reads (7%) | catalogued as COSV100108092; called by muse, mutect2
- PRR27 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs577881430, COSV60641128; called by muse, mutect2, varscan2
- PRUNE2 | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as rs1212946972, COSV100944648, COSV65047827; called by muse, mutect2
- PTGIS | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs56195291, COSV99721013; called by muse, mutect2
- RASA1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1187087405, CM1311699, COSV57191608, COSV57196650; called by muse, mutect2
- RREB1 | c.4507G>A p.V1503M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1182747579, COSV100619406; called by muse, mutect2
- SEMA3D | c.428T>A p.I143K | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV52401130, COSV99406734; called by muse, mutect2
- SIPA1L2 | c.4617G>A p.M1539I | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53395599; called by muse, mutect2, varscan2
- SLC25A13 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 106/352 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs376257669; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 50/160 reads (31%) | PolyPhen possibly damaging (0.868); catalogued as COSV50077399; called by muse, mutect2, varscan2
- STX10 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV52848545; called by muse, mutect2, varscan2
- SYCP2 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 150/394 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs369942080; called by muse, mutect2, varscan2
- TBCC | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.176); catalogued as COSV55130978; called by muse, mutect2, varscan2
- TBL1X | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54284734; called by muse, mutect2, varscan2
- TBL3 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV60342403; called by muse, mutect2, varscan2
- TBX18 | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 123/168 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63737576; called by muse, mutect2, varscan2
- TCHH | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV100915386, COSV64276441; called by muse, mutect2, varscan2
- TGM7 | c.1679-1G>A p.X560_splice | Splice Site (SNP) | VAF 4/46 reads (9%) | catalogued as rs1463492284, COSV101476864; called by muse, mutect2
- TKTL2 | c.1063T>C p.F355L | Missense Mutation (SNP) | VAF 107/203 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.269); catalogued as rs1277821291, COSV54920348; called by muse, mutect2, varscan2
- TTBK1 | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs536899086, COSV52494444; called by muse, mutect2, varscan2
- ZNF280C | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV100921236; called by muse, mutect2, varscan2
- ZNF473 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54524354, COSV99568814; called by muse, mutect2, varscan2
- ZNF486 | c.1114C>G p.H372D | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58721054; called by muse, mutect2, varscan2
- ZNF518B | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 110/310 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV58723752; called by muse, mutect2, varscan2
- CAP2 | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 5/132 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- FLNB | c.6318_6320dup p.S2107dup | In Frame Ins (INS) | VAF 40/59 reads (68%) | called by mutect2, pindel, varscan2
- IGHV3-53 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); called by mutect2, varscan2
- IGHV3-66 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 171/302 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); called by mutect2, varscan2
- SETX | c.7465_7467del p.G2489del | In Frame Del (DEL) | VAF 60/164 reads (37%) | called by pindel, varscan2
- ABCB1 | c.3609G>A p.T1203= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as rs200294906, COSV55950514; called by muse, mutect2, varscan2
- ALDH1L2 | c.909C>T p.N303= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as rs770997234, COSV51555560; called by muse, mutect2, varscan2
- ASPM | c.1563C>A p.L521= | Silent (SNP) | VAF 121/350 reads (35%) | catalogued as COSV54134583; called by muse, mutect2, varscan2
- ATAD2 | c.3768G>A p.R1256= | Silent (SNP) | VAF 72/260 reads (28%) | catalogued as COSV54884425; called by muse, mutect2, varscan2
- CHRD | c.2166C>T p.Y722= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs766572394, COSV52605082; called by muse, mutect2
- CYP2S1 | c.435C>T p.G145= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as rs763462358, COSV59506889; called by muse, mutect2, varscan2
- FRMD4A | c.570C>T p.H190= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV52730745; called by muse, mutect2, varscan2
- IL17RC | c.1644C>T p.L548= (on ENST00000295981 / NM_153461.4; = p.L462= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV55974230; called by muse, mutect2, varscan2
- KCTD17 | c.543C>T p.S181= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs577803443, COSV63248854; called by muse, mutect2, varscan2
- MYH6 | c.327C>T p.Y109= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs147148031, COSV62452139; called by muse, mutect2, varscan2
- NDUFS3 | c.579C>T p.F193= | Silent (SNP) | VAF 97/351 reads (28%) | catalogued as rs778392027; called by muse, mutect2, varscan2
- NXN | c.450G>A p.G150= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV61098694; called by muse, mutect2, varscan2
- OR2Z1 | c.378G>T p.V126= | Silent (SNP) | VAF 138/290 reads (48%) | catalogued as COSV60692956; called by muse, mutect2, varscan2
- PCDHGB4 | c.1257C>T p.T419= | Silent (SNP) | VAF 61/159 reads (38%) | catalogued as rs919430175, COSV53995197; called by muse, mutect2, varscan2
- RCBTB2 | c.1179T>A p.T393= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV60651219; called by muse, mutect2, varscan2
- RELCH | c.118C>A p.R40= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV56889236; called by muse, mutect2, varscan2
- SCAF8 | c.501G>A p.P167= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as rs143145134; called by muse, mutect2
- SERPINA10 | c.84G>A p.S28= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as rs758769939, COSV56229108; called by muse, mutect2, varscan2
- SLC2A1 | c.1185C>T p.F395= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as CD057264, COSV65287963; called by muse, mutect2, varscan2
- TAP1 | c.2334C>T p.G778= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs748368417, COSV62754209; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM74B | c.639C>T p.G213= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV67892153; called by muse, mutect2, varscan2
- TSLP | c.375G>A p.K125= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV61292131; called by muse, mutect2, varscan2
- UBAP2L | c.2187C>T p.L729= | Silent (SNP) | VAF 90/211 reads (43%) | catalogued as COSV55177877; called by muse, mutect2, varscan2
- VWF | c.5541C>T p.N1847= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as rs146540001; called by muse, mutect2, varscan2
- ZSCAN10 | c.759C>T p.L253= (on ENST00000252463; = p.L308= on NM_032805.3) | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs779835275, COSV52969579; called by muse, mutect2, varscan2
